Somatic mutation profile of tumor specimen TCGA-AA-3519-01A (aliquot TCGA-AA-3519-01A-02D-1953-10) from TCGA case TCGA-AA-3519, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 63.3 years (23,131 days).
Specimen TCGA-AA-3519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f36f428-2a6b-406c-9e0a-abb5477c83c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3519-10A (Blood Derived Normal), aliquot TCGA-AA-3519-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6edfb7da-a6a6-4663-86be-63dafdabe408

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs780713146, COSV101062969; called by muse, mutect2, varscan2
- ARRDC2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762166660, COSV55845998; called by muse, mutect2, varscan2
- ARX | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV100984049; called by muse, mutect2, varscan2
- BDP1 | c.3866A>G p.N1289S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100702988; called by mutect2, varscan2
- CCDC40 | c.2058C>A p.S686R | Missense Mutation (SNP) | VAF 108/289 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100884247; called by muse, mutect2, varscan2
- CNTLN | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99263863; called by muse, mutect2, varscan2
- CUX2 | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99919486; called by muse, mutect2
- GPR37 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100390759; called by muse, mutect2, varscan2
- KIF1C | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs147062279; called by muse, varscan2
- KLHL22 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs775705834, COSV99839254; called by muse, mutect2, varscan2
- MVD | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs942046989, COSV55367704; called by muse, mutect2, varscan2
- NOP16 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 214/597 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs778792802, COSV51257814, COSV99220928; called by muse, mutect2, varscan2
- SLC35D3 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100090489; called by muse, mutect2, varscan2
- SPNS2 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61232152; called by muse, mutect2, varscan2
- WSCD2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99774496; called by muse, mutect2, varscan2
- ZFC3H1 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs773313472, COSV101110494; called by muse, mutect2, varscan2
- ZNF205 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs746491530, COSV54620485; called by muse, mutect2, varscan2
- C16orf89 | c.261G>A p.P87= | Silent (SNP) | VAF 76/173 reads (44%) | catalogued as rs1555449540, COSV100280807; called by muse, mutect2, varscan2
- CLCA4 | c.546C>T p.I182= | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as rs370625612; called by muse, mutect2, varscan2
- HIVEP2 | c.4398C>T p.Y1466= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs762453316, COSV50007838; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNJ9 | c.438C>A p.G146= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV100927736; called by muse, mutect2, varscan2
- OTOP3 | c.1468C>A p.R490= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100172792; called by muse, mutect2, varscan2
- PLEKHN1 | c.1005C>T p.R335= (on ENST00000379409; = p.R283= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV100379077; called by muse, mutect2, varscan2
- POMC | c.693G>A p.P231= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs778888319, COSV53035332; called by muse, mutect2, varscan2
- VASN | c.1626G>C p.R542= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99227564; called by mutect2, varscan2
- PRR22 | c.194-121C>T | Intron (SNP) | VAF 24/67 reads (36%) | catalogued as rs753967174, COSV100288133; called by muse, mutect2, varscan2
